Gene-level copy-number profile of tumor specimen TCGA-PL-A8LV-01A from TCGA case TCGA-PL-A8LV, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 54.1 years (19,746 days).
Specimen TCGA-PL-A8LV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.22f1be3b-bde1-4466-9f54-316c0924a835.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-PL-A8LV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1d5c509c-5325-4d00-9235-f4291296ff8b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,708; copy number 2: 21,996; copy number 3: 8,715; copy number 4: 11,700; copy number 5: 6,814; copy number 6: 1,950; copy number 7: 1,558; copy number 8: 900; copy number 12: 148; copy number 14: 321; copy number 25: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-PL-A8LV-01A-21D-A41E-01): tumor purity 0.48, ploidy 3.25, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11,695 genes in 21 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5 (broad region; genes not listed).
- chr2:38,814–20,651,130, 312 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr2:63,517,892–64,252,859, 15 genes, copy number 6: AC016734.1, MDH1, PRELID1P6, RPS4XP5, RPL27P6, CSP1, HNRNPA1P66, UGP2, AC114748.1, VPS54, AC012368.2, PELI1, AC012368.1, LINC00309, AC012368.3.
- chr3:84,638,405–90,030,495, 44 genes, copy number 5: LINC00971, AC117482.1, LINC02025, AC132660.2, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3.
- chr3:113,716,458–114,310,288, 21 genes, copy number 6 (within-gene range 4–6): NAA50, AC108693.1, AC108693.2, ATP6V1A, GRAMD1C, AC079944.1, AC079944.2, VPS26AP1, AC128687.2, ZDHHC23, CCDC191, AC128687.1, AC128687.3, AC092896.1, QTRT2, H2BP3, DRD3, AC093010.1, FAM214BP1, ZNF80, TIGIT.
- chr3:114,314,501–114,388,978, 3 genes, copy number 6: AC093010.2, MIR568, ZBTB20-AS1.
- chr5:177,331,567–181,342,213, 168 genes, copy number 6 (broad region; genes not listed).
- chr6:2,437,549–20,334,411, 310 genes, copy number 5 (broad region; genes not listed).
- chr7:50,095,883–159,233,377, 2,138 genes, copy number 5–14 (within-gene range 2–14) (broad region; genes not listed).
- chr8:150,584–7,298,024, 128 genes, copy number 5 (broad region; genes not listed).
- chr8:10,433,672–12,756,073, 113 genes, copy number 5 (broad region; genes not listed).
- chr8:47,260,878–145,066,685, 1,504 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr9:15,553,043–16,061,663, 1 gene, copy number 5 (within-gene range 2–5): CCDC171.
- chr9:15,776,181–138,203,325, 2,106 genes, copy number 5–6 (broad region; genes not listed).
- chr11:54,682,877–60,031,077, 270 genes, copy number 14–25 (within-gene range 2–25) (broad region; genes not listed).
- chr13:61,927,090–114,337,626, 616 genes, copy number 6–7 (broad region; genes not listed).
- chr14:102,932,380–103,057,549, 1 gene, copy number 5 (within-gene range 4–5): CDC42BPB.
- chr14:103,041,469–106,875,071, 309 genes, copy number 5 (broad region; genes not listed).
- chr19:27,638,483–41,881,372, 568 genes, copy number 5 (broad region; genes not listed).
- chr19:54,200,809–58,605,223, 331 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:62,122,461–64,313,132, 133 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 5,663. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
